Somatic mutation profile of tumor specimen C3N-00860-01 (aliquot CPT0116140007) from CPTAC case C3N-00860, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 67.8 years (24,752 days).
Specimen C3N-00860-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad5d5e7d-438b-482d-b11a-32e9af937cb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00860-31 (Blood Derived Normal), aliquot CPT0116240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7cfca5a-32cd-477b-ade0-cce0a310d7dd

The open-access MAF lists 135 somatic variants for this specimen: 94 protein-altering or splice-affecting, 29 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 29, Intron 8, Nonsense Mutation 7, Frame Shift Ins 5, Splice Region 3, Frame Shift Del 3, In Frame Del 2, RNA 2, Splice Site 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 95/268 reads (35%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SOX17 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 124/663 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52023963; called by muse, mutect2, varscan2
- AATK | c.1418G>A p.R473Q (on ENST00000326724 / NM_001080395.3; = p.R370Q on NM_004920.2) | Missense Mutation (SNP) | VAF 66/438 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs888195768; called by muse, mutect2, varscan2
- ACVR2B | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 103/1104 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs2615643; called by muse, mutect2
- C10orf71 | c.3403C>T p.R1135W | Missense Mutation (SNP) | VAF 12/393 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1453021429; called by muse, mutect2
- CCDC27 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs774406117; called by muse, mutect2, varscan2
- CDC25B | c.535G>A p.E179K (on ENST00000245960 / NM_021873.3; = p.E165K on NM_004358.4) | Missense Mutation (SNP) | VAF 114/569 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs770463028; called by muse, mutect2, varscan2
- CDC73 | c.972G>A p.T324= | Splice Region (SNP) | VAF 58/521 reads (11%) | catalogued as rs369930569; called by muse, mutect2, varscan2
- CFAP46 | c.7172C>T p.A2391V | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.655); catalogued as rs140799172; called by muse, mutect2
- CLEC4F | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV55478593; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 84/673 reads (12%) | catalogued as rs1447158750, COSV70472787; called by muse, mutect2, varscan2
- CPA4 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 57/419 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs558258355; called by muse, mutect2, varscan2
- CRX | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1056691132; called by muse, mutect2, varscan2
- DCC | c.1226C>A p.A409D | Missense Mutation (SNP) | VAF 26/521 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV59104390; called by muse, mutect2
- DIPK1B | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 84/438 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148210033; called by muse, mutect2, varscan2
- DNAH7 | c.9998G>A p.R3333Q | Missense Mutation (SNP) | VAF 79/497 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1383340880, COSV56758744; called by muse, mutect2, varscan2
- DSCAM | c.4000G>T p.G1334W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1489287210; called by muse, mutect2, varscan2
- GLI2 | c.2714C>T p.A905V (on ENST00000361492 / NM_001374353.1; = p.A922V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/382 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs890177001; called by muse, mutect2, varscan2
- IRX4 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs375480367; called by muse, mutect2, varscan2
- KCNB1 | c.1748del p.R583Qfs*27 | Frame Shift Del (DEL) | VAF 37/223 reads (17%) | catalogued as COSV100870504; called by mutect2, pindel, varscan2
- LAMC3 | c.4447G>A p.E1483K | Missense Mutation (SNP) | VAF 147/1119 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367784109; called by muse, mutect2, varscan2
- LARP6 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs756707004, COSV100151030; called by muse, mutect2, varscan2
- LMF2 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs768927123; called by muse, mutect2, varscan2
- MFHAS1 | c.1695C>G p.D565E | Missense Mutation (SNP) | VAF 94/540 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.488); catalogued as rs147778000; called by muse, mutect2, varscan2
- NELL2 | c.2384C>T p.T795I | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs772134790; called by muse, mutect2, varscan2
- PAPLN | c.2596C>A p.P866T (on ENST00000554301; = p.P839T on NM_173462.4) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as rs372256808; called by muse, varscan2
- PAX2 | c.826G>A p.V276I (on ENST00000428433 / NM_003987.5; = p.V253I on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 129/899 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as rs770703982; called by muse, mutect2, varscan2
- PDE1B | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 79/353 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1318082863, COSV54491363; called by muse, mutect2, varscan2
- POU3F4 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 45/800 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM131499, COSV100937270; called by muse, mutect2
- PRAG1 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs186437273, COSV58157495; called by muse, mutect2, varscan2
- RCL1 | c.877G>C p.V293L | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV63004563; called by muse, mutect2
- RIMS2 | c.2470C>T p.R824* (on ENST00000666250 / NM_001348490.2; = p.R632* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as rs561377229, COSV51662074, COSV51700955; called by muse, mutect2, varscan2
- RTL1 | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 37/365 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1460673002, COSV66016351; called by muse, mutect2, varscan2
- RTL1 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as rs146372942; called by muse, mutect2, varscan2
- SHANK3 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781434102; called by muse, mutect2, varscan2
- SKIV2L | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.799); catalogued as rs747949471; called by muse, mutect2
- SND1 | c.1120C>G p.R374G | Missense Mutation (SNP) | VAF 18/439 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61234205; called by muse, mutect2
- SPATA5 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs756560225; called by muse, mutect2, varscan2
- TAFA4 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.154); catalogued as rs746528039, COSV55134313; called by muse, mutect2, varscan2
- TFAP2E | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138290823; called by muse, mutect2, varscan2
- TRPM3 | c.1769G>T p.R590L (on ENST00000357533 / NM_001366142.2; = p.R423L on NM_020952.6) | Missense Mutation (SNP) | VAF 19/580 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100677851; called by muse, mutect2
- UNC5D | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs768805769, COSV54794775; called by muse, mutect2, varscan2
- ZAN | c.4414G>A p.E1472K | Missense Mutation (SNP) | VAF 63/801 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.041); catalogued as rs200718653, COSV100770646; called by muse, mutect2
- ZBTB7C | c.1486G>A p.G496S | Missense Mutation (SNP) | VAF 81/353 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs895937217; called by muse, mutect2, varscan2
- ZDHHC2 | c.282G>T p.L94F | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs1563158110; called by muse, mutect2, varscan2
- ZNF572 | c.965A>G p.H322R | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774162507, COSV60001523; called by muse, mutect2, varscan2
- ALDH6A1 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 22/715 reads (3%) | called by muse, mutect2
- ATIC | c.210_212del p.A71del | In Frame Del (DEL) | VAF 121/792 reads (15%) | called by mutect2, pindel, varscan2
- C11orf95 | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.347); called by muse, mutect2
- CACNA1A | c.7016C>T p.A2339V | Missense Mutation (SNP) | VAF 106/492 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CADPS2 | c.245G>T p.R82M | Missense Mutation (SNP) | VAF 113/686 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- CARF | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CD68 | c.94_95insA p.L32Yfs*66 | Frame Shift Ins (INS) | VAF 40/235 reads (17%) | called by mutect2, pindel, varscan2
- CEP152 | c.3895G>A p.E1299K (on ENST00000380950 / NM_001194998.2; = p.E1243K on NM_014985.4) | Missense Mutation (SNP) | VAF 106/680 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP295NL | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 102/405 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CIITA | c.3004G>T p.E1002* | Nonsense Mutation (SNP) | VAF 166/822 reads (20%) | called by muse, mutect2, varscan2
- COPG2 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- CYFIP2 | c.3434T>C p.V1145A (on ENST00000616178 / NM_001291722.2; = p.V1120A on NM_014376.4) | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- DDX60 | c.1836G>C p.L612F | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DIDO1 | c.5485T>G p.S1829A | Missense Mutation (SNP) | VAF 70/347 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF2AK4 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2
- FCRL4 | c.544A>C p.K182Q | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.166); called by muse, varscan2
- FRMD8 | c.799del p.Y267Mfs*94 | Frame Shift Del (DEL) | VAF 19/124 reads (15%) | called by mutect2, pindel, varscan2
- FURIN | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- GPR180 | c.83G>C p.S28T | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGN5 | c.707A>C p.E236A | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- HSD17B7 | c.503G>A p.W168* | Nonsense Mutation (SNP) | VAF 60/454 reads (13%) | called by muse, mutect2, varscan2
- KCTD12 | c.821T>C p.F274S | Missense Mutation (SNP) | VAF 108/712 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KIF4B | c.855_878del p.F285_K292del | In Frame Del (DEL) | VAF 76/556 reads (14%) | called by mutect2, pindel
- KLHL13 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 34/313 reads (11%) | called by muse, mutect2, varscan2
- KMT2C | c.7757C>A p.S2586Y | Missense Mutation (SNP) | VAF 102/433 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- KRT71 | c.1362C>G p.S454= | Splice Region (SNP) | VAF 92/397 reads (23%) | called by muse, mutect2, varscan2
- L1CAM | c.2775C>A p.H925Q | Missense Mutation (SNP) | VAF 30/858 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.19); called by muse, mutect2
- LIN37 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- LIN7C | c.156+1del p.X52_splice | Splice Site (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- MARCHF9 | c.439A>G p.R147G | Missense Mutation (SNP) | VAF 66/437 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NAA25 | c.2380A>C p.T794P | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NHS | c.4259C>G p.T1420S | Missense Mutation (SNP) | VAF 155/626 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NID1 | c.3621A>G p.Q1207= | Splice Region (SNP) | VAF 50/334 reads (15%) | called by muse, mutect2, varscan2
- OLFM2 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR5V1 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 28/505 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PA2G4 | c.218-2A>T p.X73_splice | Splice Site (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- PAX5 | c.729G>C p.R243S | Missense Mutation (SNP) | VAF 55/381 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PDCD11 | c.1339del p.Y447Ifs*10 | Frame Shift Del (DEL) | VAF 15/161 reads (9%) | called by mutect2, pindel*
- PDS5B | c.3592dup p.S1198Kfs*2 | Frame Shift Ins (INS) | VAF 24/146 reads (16%) | called by mutect2, varscan2
- PLD1 | c.2956G>C p.V986L | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RNF43 | c.930_931dup p.L311Pfs*109 | Frame Shift Ins (INS) | VAF 42/291 reads (14%) | called by mutect2, pindel, varscan2
- SRRM2 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SSX3 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 126/693 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TEX15 | c.2654T>G p.V885G (on ENST00000256246; = p.V1268G on NM_001350162.2) | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- THBD | c.878dup p.H294Afs*35 | Frame Shift Ins (INS) | VAF 59/375 reads (16%) | called by mutect2, pindel, varscan2
- TNRC18 | c.7139T>G p.V2380G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TNS3 | c.3000T>G p.H1000Q | Missense Mutation (SNP) | VAF 171/1082 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZNF397 | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 63/478 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC090517.4 | c.199C>A p.R67= | Silent (SNP) | VAF 32/180 reads (18%) | catalogued as COSV50995788; called by muse, mutect2, varscan2
- ADAMTS16 | c.1116G>A p.L372= | Silent (SNP) | VAF 9/154 reads (6%) | catalogued as rs1225921943, COSV99943228; called by muse, mutect2
- ARHGAP36 | c.756C>T p.S252= | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as rs952393953, COSV52271126; called by muse, mutect2, varscan2
- CAST | c.840G>A p.K280= (on ENST00000341926; = p.K363= on NM_001750.7 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- CHST7 | c.1404G>A p.A468= | Silent (SNP) | VAF 53/217 reads (24%) | called by muse, mutect2, varscan2
- CLPSL1 | c.189G>A p.E63= | Silent (SNP) | VAF 70/888 reads (8%) | catalogued as rs761783889, COSV65814726; called by muse, mutect2
- CSPG4 | c.3393C>T p.N1131= | Silent (SNP) | VAF 107/774 reads (14%) | catalogued as rs772909530; called by muse, mutect2, varscan2
- DHCR24 | c.1146C>T p.H382= | Silent (SNP) | VAF 26/380 reads (7%) | catalogued as rs143696183; called by muse, mutect2
- FLG | c.5295C>T p.F1765= | Silent (SNP) | VAF 157/1333 reads (12%) | catalogued as COSV64242100; called by muse, mutect2, varscan2
- HOXD9 | c.336C>T p.P112= | Silent (SNP) | VAF 67/262 reads (26%) | called by muse, mutect2, varscan2
- INTS6 | c.2298T>A p.T766= | Silent (SNP) | VAF 48/252 reads (19%) | called by muse, mutect2, varscan2
- LONRF3 | c.1603C>T p.L535= (on ENST00000371628 / NM_001031855.3; = p.L494= on NM_024778.5) | Silent (SNP) | VAF 30/234 reads (13%) | called by muse, mutect2, varscan2
- MRC1 | c.3042C>G p.V1014= | Silent (SNP) | VAF 26/753 reads (3%) | called by muse, mutect2
- MSH5 | c.2235C>T p.C745= | Silent (SNP) | VAF 75/545 reads (14%) | catalogued as rs1174649021, COSV100991908; called by muse, mutect2, varscan2
- NDUFAF6 | c.942G>A p.Q314= | Silent (SNP) | VAF 44/300 reads (15%) | catalogued as rs1554684085; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR2T4 | c.465C>T p.Y155= | Silent (SNP) | VAF 38/1041 reads (4%) | catalogued as rs764146748, COSV100822408, COSV63543926; called by muse, mutect2
- PANK4 | c.834G>A p.K278= | Silent (SNP) | VAF 24/396 reads (6%) | called by muse, mutect2
- PCDHB11 | c.1581C>T p.F527= | Silent (SNP) | VAF 268/1556 reads (17%) | catalogued as rs868988714, COSV61309851; called by muse, mutect2, varscan2
- PCDHGC4 | c.1221G>A p.L407= | Silent (SNP) | VAF 13/201 reads (6%) | called by muse, mutect2
- PIK3C3 | c.348C>T p.P116= | Silent (SNP) | VAF 34/232 reads (15%) | catalogued as rs372601661; called by muse, mutect2, varscan2
- PROX1 | c.1677C>T p.C559= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as rs755137171, COSV54778478; called by muse, mutect2, varscan2
- SGSM3 | c.1482C>T p.H494= | Silent (SNP) | VAF 26/468 reads (6%) | catalogued as rs375483681, COSV50651561; called by muse, mutect2
- SLC12A3 | c.2130G>A p.S710= | Silent (SNP) | VAF 90/610 reads (15%) | catalogued as rs761908136; called by muse, mutect2, varscan2
- SLC12A4 | c.1239C>T p.V413= | Silent (SNP) | VAF 16/469 reads (3%) | catalogued as rs946596957, COSV100312172; called by muse, mutect2
- SLC9A4 | c.2160G>A p.R720= | Silent (SNP) | VAF 40/395 reads (10%) | catalogued as COSV54829910; called by muse, mutect2, varscan2
- TTK | c.1692T>G p.T564= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- UHRF1 | c.2226C>T p.N742= (on ENST00000612630 / NM_001290050.1; = p.N755= on NM_013282.4) | Silent (SNP) | VAF 26/450 reads (6%) | catalogued as rs767518360, COSV53573626; called by muse, mutect2
- ZNF385D | c.606G>A p.R202= | Silent (SNP) | VAF 42/263 reads (16%) | called by muse, mutect2, varscan2
- ZNF496 | c.369G>A p.E123= | Silent (SNP) | VAF 207/1867 reads (11%) | called by muse, mutect2, varscan2
- FAM136A | c.87+281T>G | Intron (SNP) | VAF 58/369 reads (16%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.1381G>T | RNA (SNP) | VAF 78/416 reads (19%) | called by muse, mutect2, varscan2
- NAPA | c.-2C>T | 5'UTR (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- PID1 | c.129+3932C>G | Intron (SNP) | VAF 52/325 reads (16%) | called by muse, mutect2, varscan2
- PLSCR3 | c.7+33T>C | Intron (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- PPP1R2P1 | n.427C>T | RNA (SNP) | VAF 54/279 reads (19%) | catalogued as rs750123594; called by muse, mutect2, varscan2
- RBM39 | c.1175-16del | Intron (DEL) | VAF 21/184 reads (11%) | called by mutect2, pindel, varscan2
- RNF121 | chr11:71929027 G>C | 5'Flank (SNP) | VAF 63/579 reads (11%) | called by muse, mutect2, varscan2
- SLC4A2 | c.51+613C>T | Intron (SNP) | VAF 19/120 reads (16%) | catalogued as rs537531817; called by muse, mutect2, varscan2
- TMEM135 | c.510-18547G>T | Intron (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- VKORC1 | c.173+225C>T | Intron (SNP) | VAF 57/283 reads (20%) | called by muse, mutect2, varscan2
- ZNF711 | c.917-887C>T | Intron (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2
